Somatic mutation profile of cancer-model specimen HCM-SANG-0283-C18-85A (3D Organoid; aliquot HCM-SANG-0283-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0283-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0283-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 670d157e-8aa5-458e-ab81-7a59535519d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0283-C18-10B (Blood Derived Normal), aliquot HCM-SANG-0283-C18-10B-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/107d473e-e7d3-4cb0-93a4-94f76f478d1e

The open-access MAF lists 191 somatic variants for this specimen: 121 protein-altering or splice-affecting, 58 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 58, Intron 8, Nonsense Mutation 6, Splice Region 4, Frame Shift Del 4, 3'UTR 3, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NAP1L3 | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 60/106 reads (57%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV59077525; called by mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 333/333 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA2 | c.6218G>A p.R2073Q (on ENST00000614293; = p.R2043Q on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/471 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.49); catalogued as rs753376326, COSV55807557; called by muse, mutect2, varscan2
- ADAM22 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 185/365 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs181573756, COSV99715519; called by muse, mutect2, varscan2
- ANK2 | c.11458C>T p.R3820W | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as rs199922285, COSV52161335; called by muse, varscan2
- ANKRD50 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 180/294 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV72385406; called by muse, mutect2, varscan2
- APC | c.3493A>T p.K1165* | Nonsense Mutation (SNP) | VAF 75/109 reads (69%) | catalogued as COSV57326930, COSV57341138; called by muse, mutect2, varscan2
- BCHE | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 56/337 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs754644618, CM080101, COSV52263033; called by muse, mutect2, varscan2
- CADPS2 | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 39/357 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1356504840; called by muse, mutect2, varscan2
- DRC1 | c.1599C>T p.S533= | Splice Region (SNP) | VAF 118/384 reads (31%) | catalogued as rs377416255; called by muse, mutect2, varscan2
- EPC1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 72/294 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs1193422736; called by muse, mutect2, varscan2
- ERF | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 78/289 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765295141; called by muse, mutect2, varscan2
- GK2 | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV62626342; called by muse, mutect2
- HOOK2 | c.1780C>T p.R594W | Missense Mutation (SNP) | VAF 129/602 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs868744992; called by muse, mutect2, varscan2
- HTR2A | c.680G>T p.C227F | Missense Mutation (SNP) | VAF 63/562 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66328125; called by muse, mutect2, varscan2
- KCNG4 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 446/588 reads (76%) | SIFT tolerated (0.14); PolyPhen benign (0.321); catalogued as rs879405372; called by muse, mutect2, varscan2
- KIAA1549L | c.3256C>T p.R1086C (on ENST00000321505; = p.R1383C on NM_012194.3) | Missense Mutation (SNP) | VAF 446/447 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368066574; called by muse, mutect2, varscan2
- KNOP1 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs764331532, COSV54929785; called by muse, mutect2, varscan2
- LHB | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 120/412 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs777561425; called by muse, mutect2, varscan2
- LMBR1 | c.575A>G p.Y192C | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1199542400; called by muse, mutect2
- MROH1 | c.2923C>T p.R975W | Missense Mutation (SNP) | VAF 160/521 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs965975680; called by muse, mutect2, varscan2
- NINL | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 436/806 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1298023886; called by muse, mutect2, varscan2
- NOLC1 | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 148/289 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.233); catalogued as rs770019664; called by muse, mutect2, varscan2
- OR52K2 | c.693del p.S232Lfs*16 | Frame Shift Del (DEL) | VAF 56/314 reads (18%) | catalogued as COSV57835488; called by mutect2, pindel, varscan2
- PCDHB7 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 594/866 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs782588805; called by muse, mutect2
- PCDHGA11 | c.1411T>C p.S471P | Missense Mutation (SNP) | VAF 16/561 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.33); catalogued as rs1412270971; called by muse, mutect2
- PIEZO1 | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 495/636 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs747301309, COSV56335461; called by muse, mutect2, varscan2
- POLN | c.2176A>G p.I726V | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as rs778707718; called by muse, mutect2, varscan2
- PRODH2 | c.529C>T p.R177W (on ENST00000301175; = p.R101W on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 335/522 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs770502391, COSV56558158; called by muse, mutect2, varscan2
- PRR27 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 88/286 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.225); catalogued as rs1245747471; called by muse, mutect2, varscan2
- PXDN | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 143/455 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.87); catalogued as rs761385604; called by muse, mutect2, varscan2
- RALB | c.281C>A p.S94* | Nonsense Mutation (SNP) | VAF 103/338 reads (30%) | catalogued as rs1242408164, COSV55602390; called by muse, mutect2, varscan2
- RRAGC | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 110/384 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.221); catalogued as rs553068233; called by muse, mutect2, varscan2
- SCAF1 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 112/381 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); catalogued as rs1347150807, COSV100862078; called by muse, mutect2, varscan2
- SLC35G3 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 108/509 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); catalogued as rs776031447, COSV52010956; called by muse, mutect2, varscan2
- SLX4 | c.4478C>T p.S1493L | Missense Mutation (SNP) | VAF 160/236 reads (68%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs565491187, COSV53563301; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPAG16 | c.1320G>T p.W440C | Missense Mutation (SNP) | VAF 92/518 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1357542399; called by muse, mutect2, varscan2
- STX19 | c.715_716del p.L239Sfs*12 | Frame Shift Del (DEL) | VAF 23/172 reads (13%) | catalogued as rs768872191; called by mutect2, pindel, varscan2
- SURF4 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 102/561 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.259); catalogued as rs148945883, COSV64332272; called by muse, mutect2, varscan2
- TDRD3 | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 87/439 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as COSV99540258; called by muse, mutect2, varscan2
- TG | c.6707C>T p.P2236L | Missense Mutation (SNP) | VAF 289/475 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145564745; called by muse, mutect2, varscan2
- TMEM63A | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 98/381 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.816); catalogued as rs778512108, COSV64764518; called by muse, mutect2, varscan2
- TSHZ1 | c.799G>A p.E267K (on ENST00000580243 / NM_001308210.2; = p.E222K on NM_005786.6) | Missense Mutation (SNP) | VAF 97/97 reads (100%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs751720440; called by muse, mutect2, varscan2
- USO1 | c.2124A>G p.L708= | Splice Region (SNP) | VAF 83/189 reads (44%) | catalogued as rs781288572; called by muse, mutect2, varscan2
- USP26 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 148/251 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs764088622, CM164474, COSV63708038; called by muse, mutect2, varscan2
- ZCCHC7 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 199/240 reads (83%) | catalogued as rs377509996; called by muse, mutect2, varscan2
- ZNF347 | c.1679A>T p.Q560L | Missense Mutation (SNP) | VAF 105/327 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.226); catalogued as COSV100498498; called by muse, mutect2, varscan2
- AC020907.6 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 92/336 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.047); called by mutect2, varscan2
- ADGRE5 | c.964G>A p.V322I (on ENST00000242786 / NM_078481.4; = p.V229I on NM_001784.5) | Missense Mutation (SNP) | VAF 125/534 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AHNAK2 | c.16923A>T p.K5641N | Missense Mutation (SNP) | VAF 87/235 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- AMN | c.233T>G p.V78G | Missense Mutation (SNP) | VAF 99/340 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ARHGEF18 | c.2301G>C p.Q767H (on ENST00000359920 / NM_001130955.2; = p.Q663H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/453 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARMCX5 | c.1600C>A p.Q534K | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- BOD1L1 | c.7291G>C p.E2431Q | Missense Mutation (SNP) | VAF 177/261 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- C2orf16 | c.1345C>T p.H449Y | Missense Mutation (SNP) | VAF 64/372 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CALCRL | c.138T>A p.Y46* | Nonsense Mutation (SNP) | VAF 44/304 reads (14%) | called by muse, mutect2, varscan2
- CARD11 | c.2782G>C p.G928R | Missense Mutation (SNP) | VAF 380/1162 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNOT3 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 14/445 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2
- CNTNAP3 | c.3125T>A p.I1042N | Missense Mutation (SNP) | VAF 41/884 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- CYFIP2 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 162/280 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CYP4A22 | c.952T>C p.F318L | Missense Mutation (SNP) | VAF 252/519 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- DNAH7 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 71/497 reads (14%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK6 | c.3361C>T p.L1121F | Missense Mutation (SNP) | VAF 26/581 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.136); called by muse, mutect2
- DPH5 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 167/273 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DYNC1H1 | c.6637A>G p.I2213V | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- EAF2 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF2AK2 | c.1441C>G p.L481V | Missense Mutation (SNP) | VAF 61/379 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHX4 | c.123G>T p.W41C | Missense Mutation (SNP) | VAF 363/364 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM47B | c.333G>T p.Q111H | Missense Mutation (SNP) | VAF 99/413 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- FBXL8 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 141/679 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FOXD4L4 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 58/962 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- GHITM | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 123/241 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.181); called by mutect2, varscan2
- GOLGA6L22 | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GOLIM4 | c.653A>C p.E218A | Missense Mutation (SNP) | VAF 85/240 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HDAC8 | c.526G>C p.D176H | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEY1 | c.700A>C p.S234R | Missense Mutation (SNP) | VAF 120/460 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IBTK | c.3692G>A p.G1231E | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IFIT1B | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 69/259 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 63/960 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- ITGA5 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- JUN | c.771_772dup p.K258Rfs*4 | Frame Shift Ins (INS) | VAF 95/357 reads (27%) | called by mutect2, pindel, varscan2
- LMCD1 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 38/404 reads (9%) | called by muse, mutect2, varscan2
- LTN1 | c.4666C>T p.L1556F | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- MESP1 | c.786del p.W262Cfs*17 | Frame Shift Del (DEL) | VAF 61/301 reads (20%) | called by mutect2, pindel, varscan2
- MTMR9 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 189/189 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- MYO7B | c.1788G>T p.E596D | Missense Mutation (SNP) | VAF 86/544 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MYO9B | c.2473C>A p.P825T | Missense Mutation (SNP) | VAF 58/340 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MZT2A | c.209T>G p.L70R | Missense Mutation (SNP) | VAF 34/429 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NCAM2 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 137/373 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPIPB5 | c.977G>T p.C326F | Missense Mutation (SNP) | VAF 233/650 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OTOGL | c.1883A>C p.D628A (on ENST00000547103; = p.D619A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCBP3 | c.1080G>A p.R360= | Splice Region (SNP) | VAF 206/539 reads (38%) | called by muse, mutect2, varscan2
- PGM2 | c.1485A>C p.E495D | Missense Mutation (SNP) | VAF 12/285 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- PKHD1 | c.10183A>G p.T3395A | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PKN3 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 94/556 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- PRDX2 | c.537del p.S180Vfs*25 | Frame Shift Del (DEL) | VAF 56/494 reads (11%) | called by mutect2, pindel, varscan2
- PRR23B | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 136/701 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RFX1 | c.1445A>C p.K482T | Missense Mutation (SNP) | VAF 98/561 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RGS4 | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 357/357 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEC16A | c.5392C>A p.P1798T | Missense Mutation (SNP) | VAF 137/275 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SERPINB5 | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 60/60 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- SLC34A2 | c.1991C>A p.T664N | Missense Mutation (SNP) | VAF 177/272 reads (65%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLITRK3 | c.1814T>A p.I605N | Missense Mutation (SNP) | VAF 52/362 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- SPEG | c.1702C>G p.P568A | Missense Mutation (SNP) | VAF 25/956 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- STARD9 | c.13892C>T p.P4631L | Missense Mutation (SNP) | VAF 78/260 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TECTA | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 88/406 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- THAP5 | c.437C>T p.S146F (on ENST00000415914 / NM_001130475.3; = p.S104F on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/354 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- THUMPD3 | c.1257C>G p.N419K | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- TIE1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 195/705 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRHDE | c.2848A>T p.R950W | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRIM56 | c.329C>G p.T110S | Missense Mutation (SNP) | VAF 72/674 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRRAP | c.4333G>C p.V1445L | Missense Mutation (SNP) | VAF 225/537 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TSACC | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 126/586 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- TTC39B | c.845A>T p.H282L | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- USH2A | c.6733C>A p.P2245T | Missense Mutation (SNP) | VAF 102/435 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- XIRP2 | c.652A>G p.T218A (on ENST00000628543; = p.T393A on NM_152381.6) | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- XKR7 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 324/1296 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ZBTB37 | c.1023G>A p.Q341= | Splice Region (SNP) | VAF 19/496 reads (4%) | called by muse, mutect2
- ZNF17 | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF253 | c.936C>A p.Y312* | Nonsense Mutation (SNP) | VAF 125/311 reads (40%) | called by muse, mutect2, varscan2
- ZNF264 | c.1677G>C p.R559S | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ABCA12 | c.7497C>A p.T2499= (on ENST00000272895 / NM_173076.3; = p.T2181= on NM_015657.3) | Silent (SNP) | VAF 56/404 reads (14%) | called by muse, mutect2, varscan2
- ADA2 | c.717C>T p.N239= | Silent (SNP) | VAF 163/163 reads (100%) | catalogued as rs142247490; called by muse, mutect2, varscan2
- AGMO | c.984A>T p.S328= | Silent (SNP) | VAF 32/512 reads (6%) | called by muse, mutect2
- ARHGAP45 | c.291C>T p.A97= | Silent (SNP) | VAF 350/998 reads (35%) | catalogued as rs143301743; called by muse, mutect2, varscan2
- ARTN | c.261G>A p.R87= (on ENST00000372354; = p.R95= on NM_057090.2) | Silent (SNP) | VAF 137/530 reads (26%) | called by muse, mutect2, varscan2
- ASIC2 | c.111G>A p.P37= | Silent (SNP) | VAF 124/504 reads (25%) | called by muse, mutect2, varscan2
- BMP2 | c.1089G>A p.P363= | Silent (SNP) | VAF 68/349 reads (19%) | catalogued as rs146731183; ClinVar: likely benign; called by muse, mutect2, varscan2
- BRSK2 | c.930C>T p.G310= | Silent (SNP) | VAF 456/456 reads (100%) | called by muse, mutect2, varscan2
- CDH13 | c.588C>T p.S196= | Silent (SNP) | VAF 77/369 reads (21%) | catalogued as rs564006725, COSV51795148; called by muse, mutect2, varscan2
- CLEC10A | c.879C>T p.D293= (on ENST00000254868 / NM_182906.4; = p.D269= on NM_006344.4) | Silent (SNP) | VAF 430/430 reads (100%) | catalogued as rs763602748, COSV99644659; called by muse, mutect2, varscan2
- CLEC2L | c.66G>A p.A22= | Silent (SNP) | VAF 10/242 reads (4%) | catalogued as rs1338819213; called by muse, mutect2
- CMYA5 | c.9948C>T p.N3316= | Silent (SNP) | VAF 64/217 reads (29%) | catalogued as rs199735788, COSV71408908; called by muse, mutect2, varscan2
- COL18A1 | c.2799C>T p.P933= (on ENST00000359759 / NM_130444.3; = p.P698= on NM_030582.4) | Silent (SNP) | VAF 392/704 reads (56%) | catalogued as rs914401777; called by muse, mutect2, varscan2
- COMMD6 | c.12C>T p.S4= | Silent (SNP) | VAF 198/827 reads (24%) | catalogued as rs1447003533; called by muse, mutect2, varscan2
- DHX34 | c.3354C>T p.P1118= | Silent (SNP) | VAF 189/301 reads (63%) | called by muse, mutect2, varscan2
- DPY19L2 | c.1968G>C p.V656= | Silent (SNP) | VAF 35/221 reads (16%) | called by muse, mutect2, varscan2
- FN3K | c.630C>T p.V210= | Silent (SNP) | VAF 78/349 reads (22%) | called by muse, mutect2, varscan2
- GABRR3 | c.735A>G p.L245= | Silent (SNP) | VAF 177/227 reads (78%) | called by muse, mutect2, varscan2
- GLIS1 | c.864C>T p.G288= | Silent (SNP) | VAF 94/309 reads (30%) | catalogued as rs766168379; called by muse, mutect2, varscan2
- GPR25 | c.204G>A p.R68= | Silent (SNP) | VAF 183/715 reads (26%) | called by muse, mutect2, varscan2
- HDC | c.429A>C p.G143= | Silent (SNP) | VAF 18/238 reads (8%) | called by muse, mutect2
- HERPUD2 | c.250C>T p.L84= | Silent (SNP) | VAF 198/482 reads (41%) | catalogued as COSV100258179; called by muse, mutect2
- ITCH | c.2262A>G p.T754= (on ENST00000262650 / NM_001257137.3; = p.T713= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/491 reads (13%) | called by muse, varscan2
- KMT5A | c.786C>T p.Y262= | Silent (SNP) | VAF 77/293 reads (26%) | catalogued as rs114151192, COSV57862373; called by muse, mutect2, varscan2
- KNTC1 | c.2160G>A p.V720= | Silent (SNP) | VAF 54/263 reads (21%) | called by muse, mutect2, varscan2
- LPXN | c.180C>T p.L60= | Silent (SNP) | VAF 33/227 reads (15%) | catalogued as rs201602799; called by muse, mutect2, varscan2
- MAGEB1 | c.108G>A p.E36= | Silent (SNP) | VAF 131/406 reads (32%) | called by muse, mutect2, varscan2
- MAN2B1 | c.147C>A p.A49= | Silent (SNP) | VAF 87/515 reads (17%) | catalogued as rs1413927578; called by muse, mutect2, varscan2
- MDH1B | c.741T>A p.A247= | Silent (SNP) | VAF 91/534 reads (17%) | called by muse, mutect2, varscan2
- MEX3B | c.421C>A p.R141= | Silent (SNP) | VAF 13/413 reads (3%) | called by muse, mutect2
- MLH1 | c.1965C>A p.I655= | Silent (SNP) | VAF 50/263 reads (19%) | called by muse, mutect2, varscan2
- NCAPD2 | c.2400G>T p.G800= | Silent (SNP) | VAF 86/580 reads (15%) | called by muse, mutect2, varscan2
- NCR1 | c.321A>G p.S107= | Silent (SNP) | VAF 122/409 reads (30%) | called by muse, mutect2, varscan2
- NCR2 | c.726G>A p.T242= | Silent (SNP) | VAF 57/387 reads (15%) | catalogued as rs1468277408, COSV66100770; called by muse, mutect2, varscan2
- NPR2 | c.297C>T p.P99= | Silent (SNP) | VAF 105/769 reads (14%) | catalogued as COSV61311037; called by muse, mutect2, varscan2
- NUBP1 | c.858C>T p.D286= | Silent (SNP) | VAF 79/296 reads (27%) | catalogued as rs376114818; called by muse, mutect2, varscan2
- OR7D4 | c.909A>G p.R303= | Silent (SNP) | VAF 202/304 reads (66%) | called by muse, mutect2, varscan2
- OVCH1 | c.1017T>G p.V339= | Silent (SNP) | VAF 162/261 reads (62%) | called by muse, mutect2, varscan2
- PABPC4L | c.201G>A p.A67= | Silent (SNP) | VAF 66/199 reads (33%) | catalogued as COSV69929061; called by muse, varscan2
- PARP12 | c.447C>G p.P149= | Silent (SNP) | VAF 74/454 reads (16%) | called by muse, mutect2, varscan2
- PAX5 | c.540C>G p.S180= | Silent (SNP) | VAF 107/633 reads (17%) | called by muse, mutect2, varscan2
- PIEZO2 | c.2349T>C p.T783= | Silent (SNP) | VAF 145/215 reads (67%) | called by muse, mutect2, varscan2
- PLIN4 | c.2088C>T p.V696= (on ENST00000301286; = p.V711= on NM_001367868.2) | Silent (SNP) | VAF 157/1382 reads (11%) | catalogued as rs780498744, COSV100013364; called by muse, mutect2, varscan2
- PNPLA3 | c.1071C>T p.P357= | Silent (SNP) | VAF 92/273 reads (34%) | called by muse, mutect2, varscan2
- QRICH1 | c.1986G>A p.K662= | Silent (SNP) | VAF 85/381 reads (22%) | called by muse, mutect2, varscan2
- RANBP2 | c.8220T>C p.C2740= | Silent (SNP) | VAF 38/306 reads (12%) | called by muse, varscan2
- RYR1 | c.12990C>G p.T4330= | Silent (SNP) | VAF 171/357 reads (48%) | catalogued as rs184450380; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- SCN7A | c.2922C>A p.I974= | Silent (SNP) | VAF 23/198 reads (12%) | called by muse, mutect2, varscan2
- SLC13A2 | c.1422T>A p.T474= | Silent (SNP) | VAF 75/407 reads (18%) | called by muse, mutect2, varscan2
- SLITRK1 | c.1647C>G p.S549= | Silent (SNP) | VAF 136/583 reads (23%) | catalogued as COSV101000107; called by muse, mutect2, varscan2
- SOCS1 | c.96G>T p.S32= | Silent (SNP) | VAF 143/731 reads (20%) | called by muse, mutect2, varscan2
- SUSD5 | c.1020C>T p.Y340= | Silent (SNP) | VAF 65/338 reads (19%) | catalogued as rs376105657, COSV58880752; called by muse, mutect2, varscan2
- TERT | c.1593C>T p.A531= | Silent (SNP) | VAF 61/317 reads (19%) | catalogued as rs146462061; ClinVar: likely benign; called by muse, mutect2, varscan2
- VANGL2 | c.1098C>T p.A366= | Silent (SNP) | VAF 92/384 reads (24%) | catalogued as rs1433597644; called by muse, mutect2, varscan2
- ZNF185 | c.639G>A p.P213= | Silent (SNP) | VAF 96/315 reads (30%) | catalogued as rs1205325568; called by muse, mutect2, varscan2
- ZNF268 | c.24T>A p.A8= | Silent (SNP) | VAF 78/355 reads (22%) | called by muse, mutect2, varscan2
- ZNF528 | c.1065T>C p.C355= | Silent (SNP) | VAF 94/324 reads (29%) | called by muse, mutect2, varscan2
- ZNF735 | c.801A>G p.K267= | Silent (SNP) | VAF 90/676 reads (13%) | called by muse, mutect2, varscan2
- AL138694.1 | n.123G>A | RNA (SNP) | VAF 140/559 reads (25%) | called by muse, mutect2, varscan2
- ANKRD44 | c.2924-1038C>T | Intron (SNP) | VAF 13/280 reads (5%) | called by muse, mutect2
- ATXN8OS | n.499+861C>T | Intron (SNP) | VAF 36/448 reads (8%) | catalogued as rs906054166; called by muse, mutect2
- BLOC1S1 | c.351+52C>A | Intron (SNP) | VAF 101/403 reads (25%) | called by muse, mutect2, varscan2
- IGSF22 | c.*364G>A | 3'UTR (SNP) | VAF 219/466 reads (47%) | called by muse, mutect2, varscan2
- INKA2 | c.*910C>T | 3'UTR (SNP) | VAF 64/208 reads (31%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-4453G>C | Intron (SNP) | VAF 44/200 reads (22%) | called by muse, mutect2, varscan2
- KIAA1958 | c.1172-26853C>T | Intron (SNP) | VAF 53/356 reads (15%) | called by muse, mutect2, varscan2
- LEKR1 | c.*1172G>A | 3'UTR (SNP) | VAF 55/285 reads (19%) | catalogued as rs375110253; called by muse, mutect2, varscan2
- PGM1 | c.247-5714T>A | Intron (SNP) | VAF 43/158 reads (27%) | called by muse, mutect2, varscan2
- RGS6 | c.1368+5228T>A | Intron (SNP) | VAF 75/225 reads (33%) | called by muse, mutect2, varscan2
- SLC8A1 | c.1915+616G>T | Intron (SNP) | VAF 42/261 reads (16%) | catalogued as rs1353306840, COSV60489520; called by muse, mutect2, varscan2
